Somatic mutation profile of tumor specimen TCGA-AC-A2FB-01A (aliquot TCGA-AC-A2FB-01A-11D-A17D-09) from TCGA case TCGA-AC-A2FB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.3 years (23,851 days).
Specimen TCGA-AC-A2FB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d51a07a5-5007-4cb1-bdbf-c3e06085eb38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A2FB-11A (Solid Tissue Normal), aliquot TCGA-AC-A2FB-11A-13D-A19T-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07030629-40ea-4de7-9003-d64ad3a0c56a

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs1378673376, COSV51029736; called by muse, mutect2, varscan2
- ANKRD1 | c.817A>T p.M273L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1232103856, COSV65468485; called by muse, mutect2, varscan2
- CDH1 | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV55728111; called by muse, mutect2
- CEP112 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.713); catalogued as COSV67144961; called by muse, mutect2
- MATN1 | c.998A>G p.H333R | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.124); catalogued as COSV101056458; called by muse, mutect2
- OSBPL10 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as rs766256601, COSV67344412; called by muse, mutect2, varscan2
- RUNX1 | c.268A>T p.K90* (on ENST00000344691 / NM_001001890.3; = p.K117* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV55894867; called by muse, mutect2
- TMEM175 | c.599C>G p.A200G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.359); catalogued as COSV53278804, COSV53281378; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BTNL8 | c.45A>G p.G15= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV99180591; called by muse, mutect2
- CD247 | c.312G>A p.K104= (on ENST00000362089 / NM_198053.3; = p.K103= on NM_000734.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV62980421; called by muse, mutect2, varscan2
